Somatic mutation profile of tumor specimen TCGA-QK-A652-01A (aliquot TCGA-QK-A652-01A-11D-A30E-08) from TCGA case TCGA-QK-A652, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.3 years (22,023 days).
Specimen TCGA-QK-A652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f28bafe6-4cce-4e1e-b79e-8b4ca357212a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A652-10A (Blood Derived Normal), aliquot TCGA-QK-A652-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0182a0be-8c0e-4372-b8a1-6db379d65620

The open-access MAF lists 43 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 32, Silent 6, Nonsense Mutation 3, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ARID1B | c.2950T>C p.Y984H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs993245785, COSV51659925; called by muse, mutect2, varscan2
- ATP2B3 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1557006556, COSV54854524; called by muse, mutect2, varscan2
- BMP3 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776862828, COSV51095050; called by muse, mutect2, varscan2
- C16orf78 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs374603360; called by muse, mutect2, varscan2
- CHPF | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs760939466, COSV99705118; called by muse, mutect2
- CTNNA2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as rs760717069, COSV100561378; called by muse, mutect2, varscan2
- DCDC1 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs761988438, COSV100663821; called by muse, mutect2, varscan2
- EFCAB14 | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100905644; called by muse, mutect2
- ELMO3 | c.1722G>T p.L574= (on ENST00000652269; = p.L521= on NM_024712.5) | Splice Region (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100440903; called by muse, mutect2, varscan2
- ELOVL3 | c.181T>A p.F61I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100892815; called by muse, mutect2, varscan2
- FRAS1 | c.8531C>T p.A2844V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV99354026; called by muse, mutect2, varscan2
- HAAO | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99685454; called by muse, mutect2, varscan2
- HUWE1 | c.12449A>T p.D4150V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99473174; called by muse, mutect2, varscan2
- INHA | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99217138; called by muse, mutect2
- INVS | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV52439663; called by muse, mutect2, varscan2
- KCNF1 | c.662C>A p.T221K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV99705759, COSV99705791; called by muse, mutect2
- KRT84 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57774016, COSV99230967; called by muse, mutect2, varscan2
- MDGA2 | c.1360C>T p.R454W (on ENST00000399232 / NM_001113498.2; = p.R156W on NM_182830.4) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775365673, COSV62078893; called by muse, mutect2, varscan2
- MYO3B | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV100510852; called by muse, mutect2, varscan2
- NOTCH1 | c.1986C>G p.Y662* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV53051277; called by muse, mutect2, varscan2
- PCDHA6 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); catalogued as rs1554132175, COSV100971631; called by muse, mutect2, varscan2
- PCDHB12 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV99507513; called by muse, mutect2, varscan2
- PCP4 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100150867; called by muse, mutect2, varscan2
- RBBP8NL | c.1928C>A p.P643H | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99436798; called by muse, mutect2, varscan2
- SIPA1L3 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99729525; called by muse, mutect2
- SLC4A3 | c.2665C>T p.Q889* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV99813011; called by muse, mutect2, varscan2
- SON | c.1892A>T p.E631V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99279162; called by muse, mutect2, varscan2
- THSD7B | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs1427538844, COSV99754412; called by muse, mutect2, varscan2
- VPS13A | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100653107; called by muse, mutect2, varscan2
- WDR49 | c.1663G>A p.D555N (on ENST00000308378 / NM_001366158.1; = p.D896N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV100393291; called by muse, mutect2, varscan2
- ZFP2 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63724806; called by muse, mutect2, varscan2
- ZNF236 | c.4324T>C p.S1442P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99470744; called by muse, mutect2, varscan2
- ZNF536 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62818001, COSV62835098; called by muse, mutect2
- ZNF594 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1360998502, COSV101280521; called by muse, mutect2, varscan2
- HTR2B | c.750_751del p.L250Ffs*22 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- DRC1 | c.1032G>A p.L344= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs771844801, COSV99985538; called by muse, mutect2, varscan2
- LDHAL6B | c.57G>A p.A19= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs763906531, COSV99896119; called by muse, mutect2, varscan2
- LIN7A | c.612A>G p.R204= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99692416; called by muse, mutect2, varscan2
- PHF12 | c.1914C>G p.T638= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV99255955; called by muse, mutect2, varscan2
- SATB2 | c.1788C>A p.P596= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV99611821; called by muse, mutect2, varscan2
- ZEB2 | c.300C>T p.N100= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs768338735, CD023855, COSV100356457; called by muse, mutect2, varscan2
